Somatic mutation profile of tumor specimen MP2PRT-PAVITN-TMP1-A (aliquot MP2PRT-PAVITN-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVITN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,492 days).
Specimen MP2PRT-PAVITN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e2b71d-0bbf-45e3-98c3-081aaae57264.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVITN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVITN-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c864e6a7-3565-4649-b431-720ab6bb873d

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, In Frame Ins 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL7R | c.727_728insCATGCT p.L242_L243insPC | In Frame Ins (INS) | VAF 24/285 reads (8%) | catalogued as COSV57406244, COSV57406538, COSV57408312, COSV57408637, COSV57411199, COSV57411469, COSV57413100, COSV99073420; called by mutect2, pindel
- MYO16 | c.2036C>A p.A679D | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV51791810; called by muse, mutect2, varscan2
- NDUFB3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772960455; called by muse, mutect2, varscan2
- PKD1L3 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1030970822; called by muse, mutect2, varscan2
- AL136295.1 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INPP5A | c.424dup p.S142Kfs*38 | Frame Shift Ins (INS) | VAF 48/428 reads (11%) | called by mutect2, pindel, varscan2
- KIF1A | c.3904C>T p.R1302C (on ENST00000320389 / NM_001379639.1; = p.R1294C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/690 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRIG1 | c.1969T>C p.F657L | Missense Mutation (SNP) | VAF 258/542 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PERM1 | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R13L | c.389A>C p.D130A | Missense Mutation (SNP) | VAF 70/1231 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- TRDD2 | c.6_7insCCA p.S2_Y3insP | In Frame Ins (INS) | VAF 143/164 reads (87%) | called by mutect2, pindel*, varscan2
- FGFR1 | c.1020G>A p.T340= (on ENST00000447712 / NM_023110.3; = p.T338= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 172/426 reads (40%) | catalogued as rs762987116; called by mutect2, varscan2
- NT5C1A | c.684C>T p.H228= | Silent (SNP) | VAF 189/643 reads (29%) | catalogued as rs140258838; called by muse, mutect2, varscan2
